MMRF case MMRF_1918 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a47491e6-0715-4fd9-8cbb-deb2d286d14f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,629 days); ISS stage: I; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 273 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 286 days; Days to treatment end: 287 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 456 days (1.2 years); Days to treatment end: 471 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 456 days (1.2 years); Days to treatment end: 631 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 484 days (1.3 years); Days to treatment end: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 547 days (1.5 years); Days to treatment end: 625 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 659 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 997.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -80 (ECOG 0): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 120 mg/dL; Immunoglobulin G 71.7 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.27 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 12.7 g/dL; Glucose 5.17 mmol/L.
- Day 63 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.31 mg/dL; Immunoglobulin G 18.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.28 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 338 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.
- Day 113 (ECOG 0): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.35 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.68 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 404 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 4.35 mmol/L.
- Day 214 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.18 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 374 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 6.27 mmol/L.
- Day 308 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.6 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.83 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 78.7 µmol/L; Calcium 2.75 mmol/L; Albumin 41 g/L.
- Day 347 (ECOG 0): Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.9 ×10⁹/L; Platelets 318 ×10⁹/L; Creatinine 62.8 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L.
- Day 451 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.1 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 37.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 547 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 5.18 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.19 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 644 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 4.53 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 723 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.25 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 4.62 mmol/L.
- Day 799 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 5.08 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.19 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 889 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 980 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 0.68 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day -80: Weight: 81 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1918_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -80 days.
- Sample MMRF_1918_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -80 days.
